Somatic mutation profile of tumor specimen MP2PRT-PASZGH-TMP1-A (aliquot MP2PRT-PASZGH-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASZGH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,782 days).
Specimen MP2PRT-PASZGH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e147255-ace2-43bc-9303-a90768f21e96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZGH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZGH-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7d3b0d0-deb7-42f8-996d-6597209117f9

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, 3'Flank 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf47 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 200/453 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs754519104; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLT1A | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs761018559, COSV57643516; called by muse, mutect2
- HTR4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 101/324 reads (31%) | catalogued as rs1271130452; called by muse, mutect2, varscan2
- KCTD11 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 215/472 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1003048018, COSV99341307; called by muse, mutect2, varscan2
- NAP1L2 | c.400C>G p.H134D | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65172314; called by muse, mutect2
- CHST10 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.224); called by muse, mutect2
- DNAJC2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ECM2 | c.135C>A p.H45Q | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- FTSJ1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 199/508 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NIBAN2 | c.2238C>G p.F746L | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- NWD1 | c.2037_2038insCC p.V680Pfs*28 | Frame Shift Ins (INS) | VAF 187/512 reads (37%) | called by mutect2, pindel, varscan2
- PPP1R12B | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 326/798 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PTPRM | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/566 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- SCN5A | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2
- ZRANB3 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- ALPG | c.546G>A p.T182= | Silent (SNP) | VAF 280/612 reads (46%) | catalogued as rs1413173548; called by muse, mutect2, varscan2
- KIAA1109 | c.10824G>A p.L3608= | Silent (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937680 del C | 3'Flank (DEL) | VAF 52/72 reads (72%) | called by mutect2, pindel*, varscan2
